Gene-level copy-number profile of tumor specimen TCGA-NG-A4VU-01A from TCGA case TCGA-NG-A4VU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Age at diagnosis: 63.9 years (23,323 days).
Specimen TCGA-NG-A4VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.94db45fa-ae40-43d0-a1e1-e1601455e33b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NG-A4VU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a20ce0d-ad44-4a7b-b8da-31dbac6698d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 144; copy number 1: 1,983; copy number 2: 30,426; copy number 3: 14,461; copy number 4: 10,379; copy number 5: 855; copy number 6: 1,259; copy number 7: 210; copy number 8: 100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NG-A4VU-01A-11D-A28Q-01): tumor purity 0.92, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–2): LSAMP.
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:150,584–7,187,316, 114 genes (within-gene range 0–2) (broad region; genes not listed).
- chr11:6,748,131–7,071,526, 14 genes (within-gene range 0–2): GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2, OR2D3, ZNF215, ZNF214, NLRP14.
- chr12:99,647,753–99,650,114, 1 gene: FAM71C.
- chr21:16,035,413–16,035,509, 1 gene: RNU6-426P.
- chr21:16,862,875–17,296,596, 3 genes: AF212831.1, NEK4P1, AP000457.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,424 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,648,411–158,100,262, 716 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:162,039,016–162,039,567, 1 gene, copy number 6: AL590408.1.
- chr2:98,331,389–99,154,964, 14 genes, copy number 8: AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1.
- chr2:99,141,707–99,195,298, 4 genes, copy number 8 (within-gene range 4–8): C2orf15, LIPT1, AC092587.1, MITD1.
- chr2:119,759,922–124,025,173, 50 genes, copy number 5: PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1.
- chr2:154,964,308–184,002,264, 435 genes, copy number 5 (broad region; genes not listed).
- chr2:189,879,609–190,203,484, 5 genes, copy number 5 (within-gene range 3–5): C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN.
- chr3:168,249,522–169,663,775, 13 genes, copy number 8 (within-gene range 3–8): EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1.
- chr6:62,460,940–63,319,983, 8 genes, copy number 5: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN.
- chr6:162,727,132–170,738,536, 156 genes, copy number 6–7 (broad region; genes not listed).
- chr7:70,837,738–72,447,151, 9 genes, copy number 6: AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2.
- chr7:95,471,835–97,024,950, 23 genes, copy number 5: AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5.
- chr7:104,328,700–105,522,271, 19 genes, copy number 5–7 (within-gene range 3–7): LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7.
- chr7:120,273,175–120,858,402, 4 genes, copy number 6 (within-gene range 2–7): KCND2, RNU6-581P, AC004888.1, TSPAN12.
- chr8:35,235,475–35,796,550, 1 gene, copy number 7 (within-gene range 4–7): UNC5D.
- chr8:35,525,176–39,730,065, 91 genes, copy number 7 (broad region; genes not listed).
- chr8:40,519,565–51,015,165, 161 genes, copy number 5–8 (broad region; genes not listed).
- chr8:68,293,446–70,078,032, 27 genes, copy number 5: RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P.
- chr8:95,204,456–95,811,254, 1 gene, copy number 5 (within-gene range 4–5): C8orf37-AS1.
- chr8:95,244,913–110,349,607, 252 genes, copy number 5–8 (broad region; genes not listed).
- chr11:34,105,617–35,138,032, 17 genes, copy number 8: NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1.
- chr11:42,939,775–44,084,237, 34 genes, copy number 5: AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1.
- chr16:1,580,527–2,209,453, 64 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:59,674,636–60,422,470, 35 genes, copy number 6 (within-gene range 2–6): PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42.
- chr19:9,959,561–13,961,449, 245 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:49,113,339–50,321,342, 39 genes, copy number 5 (within-gene range 4–5): STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.

Autosomal genes at a single copy (total copy number 1): 894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
